Somatic mutation profile of tumor specimen TCGA-CV-7440-01A (aliquot TCGA-CV-7440-01A-11D-2129-08) from TCGA case TCGA-CV-7440, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: GX; Age at diagnosis: 38.3 years (13,992 days).
Specimen TCGA-CV-7440-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d519c99e-76a9-42e8-91cf-a5d8fd49047e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7440-10A (Blood Derived Normal), aliquot TCGA-CV-7440-10A-01D-2129-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8e4b772-fdc4-4444-8c2b-c43207f1862b

The open-access MAF lists 230 somatic variants for this specimen: 190 protein-altering or splice-affecting, 35 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 146, Silent 35, Frame Shift Del 16, Nonsense Mutation 15, Splice Site 7, Intron 3, Splice Region 2, Frame Shift Ins 2, In Frame Del 2, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.1855A>T p.K619* (on ENST00000272895 / NM_173076.3; = p.K301* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99791962; called by muse, mutect2, varscan2
- ABCA13 | c.3062T>A p.L1021H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101330172; called by muse, mutect2, varscan2
- ACAN | c.2413C>A p.P805T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.094); catalogued as COSV100719235, COSV61358110; called by muse, mutect2, varscan2
- ACSL4 | c.1801A>G p.I601V (on ENST00000340800 / NM_022977.2; = p.I560V on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.773); catalogued as COSV100539063; called by muse, mutect2, varscan2
- ACTG1 | c.770G>A p.C257Y | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100112061; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1847C>A p.T616N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as COSV99721129; called by muse, mutect2, varscan2
- ADGRL3 | c.1641C>G p.D547E (on ENST00000506720 / NM_001322402.2; = p.D479E on NM_015236.6) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV101547385, COSV72231661; called by muse, mutect2, varscan2
- ADSL | c.871G>T p.A291S | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99342571; called by muse, mutect2, varscan2
- ADSL | c.872C>G p.A291G | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53407861, COSV99342574; called by muse, mutect2, varscan2
- AHNAK | c.12766A>G p.K4256E | Missense Mutation (SNP) | VAF 64/421 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV99949528; called by muse, mutect2, varscan2
- ALG13 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.122); catalogued as rs1381653955, COSV99322989; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD30A | c.435T>G p.Y145* (on ENST00000611781; = p.Y89* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100654426; called by muse, mutect2, varscan2
- ANKRD46 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); catalogued as COSV100170248; called by muse, mutect2, varscan2
- ARID1A | c.3947C>A p.S1316* | Nonsense Mutation (SNP) | VAF 44/88 reads (50%) | catalogued as COSV100250732; called by muse, varscan2
- ASPM | c.3610G>C p.E1204Q | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.625); catalogued as COSV99659457, COSV99661090; called by muse, mutect2, varscan2
- ASXL3 | c.3343C>G p.Q1115E | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs1378369324, COSV99326516; called by muse, mutect2, varscan2
- ATP2B2 | c.1783C>T p.R595C (on ENST00000352432; = p.R561C on NM_001683.5) | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776463160, COSV59494867; called by muse, mutect2, varscan2
- ATP2B3 | c.610C>A p.L204I | Missense Mutation (SNP) | VAF 67/95 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99685800; called by muse, mutect2, varscan2
- ATRX | c.4333G>C p.E1445Q | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV100971417, COSV64875081; called by muse, mutect2, varscan2
- BEX4 | c.23C>A p.A8E | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV101015419, COSV104425074; called by muse, mutect2, varscan2
- BRD8 | c.3521T>C p.L1174P | Missense Mutation (SNP) | VAF 68/345 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99496972; called by muse, mutect2, varscan2
- C12orf40 | c.884A>C p.N295T | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as rs780692136, COSV100210766; called by muse, mutect2, varscan2
- CAMTA1 | c.1879G>T p.V627F | Missense Mutation (SNP) | VAF 85/180 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV100352348; called by muse, mutect2, varscan2
- CC2D2A | c.2587A>G p.N863D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101052927; called by muse, mutect2, varscan2
- CELSR1 | c.4772C>T p.S1591F | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.919); catalogued as COSV99419999; called by muse, mutect2, varscan2
- CEP112 | c.858T>C p.I286= | Splice Region (SNP) | VAF 7/20 reads (35%) | catalogued as COSV101211136; called by muse, mutect2, varscan2
- CFH | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100661632; called by muse, mutect2, varscan2
- CHRM2 | c.888G>C p.M296I | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100281913; called by muse, mutect2, varscan2
- CILP | c.2324T>C p.I775T | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV99973912; called by muse, mutect2, varscan2
- CNTN6 | c.2872A>G p.T958A | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs745387023, COSV100611826; called by muse, mutect2, varscan2
- COL20A1 | c.3660del p.M1221Cfs*? | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as COSV100491399; called by mutect2, pindel, varscan2
- COL4A1 | c.2152T>C p.F718L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.961); catalogued as COSV101011580; called by muse, mutect2, varscan2
- COL5A2 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100880792, COSV66412045; called by muse, mutect2, varscan2
- CRTC3 | c.212G>A p.S71N | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1339118222, COSV99185808; called by muse, mutect2, varscan2
- CSMD3 | c.10336G>T p.G3446C (on ENST00000297405 / NM_001363185.1; = p.G3277C on NM_052900.3) | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99845724, COSV99847239; called by muse, mutect2, varscan2
- CSNK2A1 | c.78C>A p.Y26* | Nonsense Mutation (SNP) | VAF 37/79 reads (47%) | catalogued as COSV99424703; called by muse, mutect2, varscan2
- CYP4F2 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50000269, COSV99171140; called by muse, mutect2
- DCAF4L2 | c.20G>C p.R7P | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as COSV100151281, COSV60477090; called by muse, mutect2, varscan2
- DCDC1 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100664171, COSV60848936; called by muse, mutect2, varscan2
- DENND2B | c.1630C>G p.L544V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.58); catalogued as COSV100567833; called by muse, varscan2
- DHX8 | c.1005G>A p.M335I | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV99292621; called by muse, mutect2, varscan2
- DNAH7 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs368206641; called by muse, mutect2, varscan2
- DNAI4 | c.2251T>G p.Y751D | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV100925499; called by muse, mutect2, varscan2
- EDN3 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.391); catalogued as rs765355566, COSV100285111; called by muse, mutect2, varscan2
- EEA1 | c.1404G>T p.Q468H | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.186); catalogued as COSV100468491; called by muse, mutect2, varscan2
- EGLN1 | c.784A>C p.K262Q | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100791330; called by muse, mutect2, varscan2
- EIF2B3 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs776568212, COSV100838987; called by muse, varscan2
- ENPP3 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV100718057; called by muse, mutect2, varscan2
- EPHA2 | c.153+1G>C p.X51_splice | Splice Site (SNP) | VAF 46/131 reads (35%) | catalogued as COSV100626279; called by muse, mutect2, varscan2
- ESPL1 | c.2708A>T p.Q903L | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV99229751; called by muse, mutect2, varscan2
- FAM155A | c.170G>T p.W57L | Missense Mutation (SNP) | VAF 78/159 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101030336; called by muse, mutect2, varscan2
- FAM184A | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100138350; called by muse, mutect2, varscan2
- FBXL13 | c.704C>A p.P235H | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.396); catalogued as COSV100502102; called by muse, mutect2, varscan2
- FER1L5 | c.6057G>A p.P2019= (on ENST00000623019; = p.P1983= on NM_001293083.2) | Splice Region (SNP) | VAF 64/201 reads (32%) | catalogued as rs764358931, COSV53843542; called by muse, mutect2, varscan2
- FER1L6 | c.2749A>G p.T917A | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.821); catalogued as COSV101206179; called by muse, mutect2, varscan2
- FMO4 | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774083463, COSV100882172; called by muse, mutect2, varscan2
- FRMPD4 | c.1854T>A p.C618* | Nonsense Mutation (SNP) | VAF 51/85 reads (60%) | catalogued as COSV101044051; called by muse, mutect2, varscan2
- GAL3ST4 | c.1319G>T p.R440L | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV100385396, COSV100385638; called by muse, mutect2, varscan2
- GALNT14 | c.1589G>C p.G530A | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as COSV100205561; called by muse, mutect2, varscan2
- GAREM1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs762101462, COSV52505737, COSV99330147; called by muse, mutect2, varscan2
- GFRA1 | c.362A>T p.Y121F | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100816137; called by muse, mutect2, varscan2
- GJA8 | c.445A>T p.R149W | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99569691; called by muse, mutect2, varscan2
- GLRB | c.652G>T p.G218* | Nonsense Mutation (SNP) | VAF 14/99 reads (14%) | catalogued as COSV100030138; called by muse, mutect2, varscan2
- GPAA1 | c.1492C>A p.L498M | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1554764272, COSV100284210; called by muse, mutect2, varscan2
- GRAMD1C | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs868500070, COSV100823000, COSV63982771; called by muse, mutect2, varscan2
- GRID1 | c.1160G>T p.S387I | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV100026436; called by muse, mutect2, varscan2
- HDGFL2 | c.1667A>G p.E556G | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as COSV56681508; called by muse, mutect2, varscan2
- HEPH | c.3188T>C p.F1063S (on ENST00000343002; = p.F796S on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as COSV100295694, COSV57966301; called by muse, mutect2, varscan2
- HIF3A | c.815G>C p.C272S (on ENST00000377670 / NM_152795.4; = p.C203S on NM_022462.4) | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.148); catalogued as COSV99356054; called by muse, mutect2, varscan2
- HUWE1 | c.449G>C p.R150P | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53352774, COSV99470701; called by muse, mutect2, varscan2
- IFIH1 | c.1674G>T p.M558I | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99718882; called by muse, mutect2, varscan2
- IGHMBP2 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs138448914; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IPO7 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.221); catalogued as rs1173346441, COSV101121850; called by muse, mutect2, varscan2
- IQGAP2 | c.2410G>T p.V804F | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs781453969, COSV99168004; called by muse, mutect2, varscan2
- ITGA8 | c.2041del p.E681Kfs*10 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as rs1333215733, COSV65229170; called by mutect2, pindel, varscan2
- ITPR2 | c.1549C>T p.Q517* | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as COSV101190160; called by muse, mutect2, varscan2
- JDP2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.818); catalogued as COSV99966799; called by muse, mutect2, varscan2
- KCTD3 | c.398-2A>G p.X133_splice | Splice Site (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99379723; called by muse, mutect2, varscan2
- KIDINS220 | c.2592C>A p.D864E | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.047); catalogued as COSV99876447; called by muse, mutect2, varscan2
- KIF2B | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs1479427821, COSV52127121; called by muse, mutect2, varscan2
- KRT34 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.721); catalogued as COSV101222721; called by muse, mutect2, varscan2
- L3MBTL1 | c.2324T>A p.I775N (on ENST00000418998 / NM_001377303.1; = p.I685N on NM_015478.7) | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100917059; called by muse, mutect2, varscan2
- L3MBTL4 | c.1816C>T p.H606Y | Missense Mutation (SNP) | VAF 49/241 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as rs1231410992, COSV99531065; called by muse, mutect2, varscan2
- LAMA2 | c.4620C>G p.D1540E | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101370823; called by muse, mutect2, varscan2
- LAMA2 | c.5320G>T p.E1774* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as COSV101370824; called by muse, mutect2, varscan2
- LAMA5 | c.3217C>T p.R1073W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1256118723, COSV99442226; called by muse, mutect2, varscan2
- LHFPL6 | c.434G>A p.S145N | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.194); catalogued as rs142526688; called by muse, mutect2, varscan2
- LRFN5 | c.1948A>G p.K650E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.265); catalogued as rs1391527202, COSV53256577; called by muse, mutect2, varscan2
- LRP1B | c.13222C>G p.P4408A | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV101260819, COSV67224113; called by muse, mutect2, varscan2
- LRP1B | c.5219T>C p.I1740T | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV101260823; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.229); catalogued as COSV61010051; called by muse, mutect2, varscan2
- MMEL1 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.46); PolyPhen benign (0.097); catalogued as rs1226789469, COSV56522164; called by muse, mutect2, varscan2
- MMP13 | c.382G>C p.D128H | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52824294, COSV99506849; called by muse, mutect2, varscan2
- MMRN1 | c.1662G>T p.K554N | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV99307757; called by muse, mutect2, varscan2
- MYH15 | c.5827-2A>C p.X1943_splice | Splice Site (SNP) | VAF 64/175 reads (37%) | catalogued as COSV99844284; called by muse, mutect2, varscan2
- MYH4 | c.1587+2T>A p.X529_splice | Splice Site (SNP) | VAF 17/73 reads (23%) | catalogued as COSV99702201; called by muse, mutect2, varscan2
- MYO19 | c.2767_2768del p.K923Vfs*12 (on ENST00000614623 / NM_001163735.1; = p.K723Vfs*12 on NM_025109.5) | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs753665430; called by mutect2, pindel, varscan2
- MYOCD | c.2158C>T p.P720S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs748200406, COSV58503641; called by muse, mutect2, varscan2
- MYOM1 | c.3197G>A p.G1066E | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1258368446, COSV99868354; called by muse, mutect2, varscan2
- NCR2 | c.803G>C p.S268T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.024); catalogued as COSV100897259; called by muse, mutect2, varscan2
- NLRC3 | c.2330A>G p.N777S | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1213332144, COSV100073388; called by muse, mutect2, varscan2
- NLRP12 | c.933C>A p.C311* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100145891; called by muse, mutect2, varscan2
- NPHS1 | c.679C>A p.P227T | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV100800261; called by muse, mutect2, varscan2
- NPPB | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV64687567; called by muse, mutect2, varscan2
- NSD1 | c.2376C>A p.C792* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV100729787; called by muse, mutect2, varscan2
- NSD1 | c.4856G>C p.C1619S | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100729788, COSV61773987; called by muse, mutect2, varscan2
- OR4N2 | c.894G>T p.M298I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV100269985, COSV60050009; called by muse, mutect2
- OR52N4 | c.323C>G p.T108S | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.211); catalogued as COSV100421759; called by muse, mutect2, varscan2
- OR5B3 | c.879G>C p.K293N | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as COSV100512069; called by muse, mutect2, varscan2
- PAAF1 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100142718; called by muse, mutect2, varscan2
- PAPPA | c.3598C>A p.P1200T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.24); catalogued as COSV100075268; called by muse, mutect2, varscan2
- PARD3 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as COSV100401988; called by muse, mutect2, varscan2
- PCDH10 | c.1990G>T p.G664W | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99994473; called by muse, mutect2, varscan2
- PCDHB12 | c.213C>A p.N71K | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); catalogued as rs145009914; called by muse, mutect2, varscan2
- PCLO | c.7324A>T p.K2442* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV100437641; called by muse, mutect2
- PCYT2 | c.515A>G p.E172G | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV100155738; called by muse, mutect2
- PDX1 | c.555G>C p.L185F | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66847090; called by muse, mutect2
- PIGK | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.101); catalogued as COSV100769946; called by muse, mutect2, varscan2
- PIK3C2B | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs747174511, COSV65810903; called by muse, mutect2, varscan2
- PLCL1 | c.1947C>G p.I649M | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.715); catalogued as COSV101407282; called by muse, mutect2
- PPP4R3B | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99702688; called by muse, mutect2, varscan2
- PTP4A3 | c.313G>T p.V105L | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV100267440, COSV61471428; called by muse, mutect2, varscan2
- PTPRB | c.3691G>A p.G1231S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as rs1370264411, COSV99718913; called by muse, mutect2, varscan2
- RGL1 | c.1534C>T p.R512W (on ENST00000360851 / NM_001297672.2; = p.R547W on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.948); catalogued as rs371044087; called by muse, mutect2, varscan2
- RIMS3 | c.359+1G>T p.X120_splice | Splice Site (SNP) | VAF 16/78 reads (21%) | catalogued as COSV101013588, COSV65504211, COSV65505346; called by muse, mutect2, varscan2
- RIPK2 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV99610119; called by muse, mutect2, varscan2
- RLF | c.5514G>C p.E1838D | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV101035684; called by muse, mutect2, varscan2
- SEC31A | c.3221G>C p.G1074A (on ENST00000355196 / NM_001318120.1; = p.G1035A on NM_016211.4) | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs368504379, COSV100022295; called by muse, mutect2, varscan2
- SEMA5A | c.1129C>G p.Q377E | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs147170997, COSV101228731; called by muse, mutect2, varscan2
- SGMS2 | c.968A>T p.K323I | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV100763524; called by muse, mutect2, varscan2
- SLC35F1 | c.413T>C p.I138T | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as rs1030022120, COSV100838122; called by muse, mutect2, varscan2
- SLC35F3 | c.395G>A p.R132Q (on ENST00000366617 / NM_001300845.1; = p.R201Q on NM_173508.4) | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.171); catalogued as COSV100784797, COSV64018423; called by muse, mutect2, varscan2
- SLC35G3 | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 97/234 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV52010668, COSV99269229; called by muse, mutect2, varscan2
- SLC7A14 | c.2138A>G p.E713G | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99200983; called by muse, mutect2, varscan2
- SLIT3 | c.2720-2A>C p.X907_splice | Splice Site (SNP) | VAF 6/53 reads (11%) | catalogued as COSV100269784; called by muse, mutect2, varscan2
- SNRPN | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV57600654; called by muse, mutect2, varscan2
- SPATA31E1 | c.3127C>T p.P1043S | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.143); catalogued as rs1232083010, COSV100351055; called by muse, mutect2, varscan2
- SPDL1 | c.159G>C p.E53D | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99517761; called by muse, mutect2, varscan2
- SVEP1 | c.9683A>G p.E3228G | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.136); catalogued as COSV99929778; called by muse, mutect2, varscan2
- SYBU | c.1717C>G p.L573V (on ENST00000276646 / NM_001099754.2; = p.L572V on NM_017786.6) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV99406637; called by muse, mutect2, varscan2
- SYNE3 | c.851C>A p.A284E | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143391386, COSV62077866; called by muse, mutect2, varscan2
- TASOR2 | c.3626C>G p.S1209* | Nonsense Mutation (SNP) | VAF 21/94 reads (22%) | catalogued as COSV100051008; called by muse, mutect2, varscan2
- TCTN1 | c.1046G>T p.G349V (on ENST00000551590 / NM_001173975.3; = p.G335V on NM_024549.6) | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100886248; called by muse, mutect2, varscan2
- TDG | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV99904343; called by muse, mutect2, varscan2
- TFIP11 | c.1336A>T p.T446S | Missense Mutation (SNP) | VAF 110/175 reads (63%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99314824; called by muse, mutect2, varscan2
- TMEM132A | c.1078G>T p.G360C (on ENST00000453848 / NM_178031.3; = p.G361C on NM_017870.4) | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV99070845; called by muse, mutect2, varscan2
- TMEM167A | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.856); catalogued as COSV101491876; called by muse, mutect2, varscan2
- TMEM213 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs200306735; called by muse, mutect2, varscan2
- TMPRSS9 | c.868G>A p.A290T (on ENST00000648592; = p.A256T on NM_182973.2) | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV100210898; called by muse, mutect2, varscan2
- TRIM42 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99648822; called by muse, mutect2, varscan2
- TRPM3 | c.5072G>T p.S1691I (on ENST00000357533 / NM_001366142.2; = p.S1546I on NM_020952.6) | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs777300541, COSV62592354; called by muse, mutect2, varscan2
- TRRAP | c.11386G>T p.A3796S (on ENST00000359863 / NM_001244580.1; = p.A3767S on NM_003496.3) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as rs749974582, COSV100705493; called by muse, mutect2, varscan2
- TSEN34 | c.293G>A p.S98N | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99825045; called by muse, mutect2, varscan2
- TSR3 | c.623G>T p.C208F | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1454783649, COSV99136375; called by muse, mutect2, varscan2
- UBQLNL | c.474A>T p.K158N | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV100975510; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3919G>T p.A1307S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.164); catalogued as COSV99692137; called by muse, varscan2
- UNC79 | c.4835C>G p.S1612* (on ENST00000393151 / NM_001346218.2; = p.S1435* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 36/142 reads (25%) | catalogued as COSV99829802; called by muse, mutect2, varscan2
- USP17L2 | c.1573G>T p.A525S | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779810100, COSV100414734; called by muse, mutect2, varscan2
- VIRMA | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV99889443; called by muse, mutect2, varscan2
- WDR55 | c.492G>T p.M164I | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.11); catalogued as COSV100845602; called by muse, mutect2, varscan2
- WDR90 | c.841-1G>T p.X281_splice | Splice Site (SNP) | VAF 22/72 reads (31%) | catalogued as COSV99554145; called by muse, mutect2, varscan2
- WWC1 | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV99515886; called by muse, mutect2, varscan2
- XKR3 | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100509378; called by muse, mutect2, varscan2
- ZHX3 | c.763G>T p.G255W | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100475898; called by muse, mutect2, varscan2
- ZNF135 | c.1234T>A p.C412S (on ENST00000313434 / NM_001289401.2; = p.C424S on NM_003436.4) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1260746519, COSV100536879; called by muse, mutect2, varscan2
- ZNF398 | c.35G>T p.W12L | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.431); catalogued as COSV100247050; called by muse, mutect2, varscan2
- ZNF432 | c.1301G>T p.C434F | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99659380; called by muse, mutect2, varscan2
- ZNF471 | c.261G>T p.W87C | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.258); catalogued as COSV100340865; called by muse, mutect2, varscan2
- ZNF506 | c.1248G>C p.K416N | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV101475663; called by muse, mutect2, varscan2
- ZNF862 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV99783802; called by muse, mutect2
- ADCY4 | c.2727del p.F909Lfs*29 | Frame Shift Del (DEL) | VAF 23/75 reads (31%) | called by mutect2, pindel, varscan2
- ALPP | c.100_112del p.W34Qfs*34 | Frame Shift Del (DEL) | VAF 14/112 reads (13%) | called by mutect2, pindel
- AMPD1 | c.1915del p.Y639Tfs*5 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, varscan2
- ANKRD30A | c.3399del p.F1133Lfs*7 (on ENST00000611781; = p.F1077Lfs*7 on NM_052997.2) | Frame Shift Del (DEL) | VAF 20/110 reads (18%) | called by mutect2, pindel, varscan2
- CHEK2 | c.1096_1106del p.T366Lfs*14 (on ENST00000382580 / NM_001005735.2; = p.T323Lfs*14 on NM_007194.4) | Frame Shift Del (DEL) | VAF 72/186 reads (39%) | called by mutect2, pindel, varscan2
- CYP4F2 | c.711T>G p.H237Q | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ERBB3 | c.2085_2090del p.K695_A696del | In Frame Del (DEL) | VAF 51/204 reads (25%) | called by mutect2, pindel, varscan2
- IL19 | c.167del p.N56Mfs*17 | Frame Shift Del (DEL) | VAF 22/189 reads (12%) | called by mutect2, pindel, varscan2
- LIN28B | c.374dup p.D127Rfs*2 | Frame Shift Ins (INS) | VAF 20/109 reads (18%) | called by mutect2, pindel
- MBL2 | c.191_215del p.Q64Pfs*69 | Frame Shift Del (DEL) | VAF 32/163 reads (20%) | called by mutect2, pindel
- NETO1 | c.82_82+1insT p.E28Vfs*38 | Frame Shift Ins (INS) | VAF 3/28 reads (11%) | called by mutect2, pindel
- OR8G2P | c.800C>A p.S267Y | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- POM121C | c.2587A>T p.K863* (on ENST00000607367; = p.K621* on NM_001099415.3) | Nonsense Mutation (SNP) | VAF 39/153 reads (25%) | called by muse, mutect2, varscan2
- PRXL2A | c.425del p.G142Vfs*7 | Frame Shift Del (DEL) | VAF 30/142 reads (21%) | called by mutect2, pindel, varscan2
- RNF181 | c.279_283del p.C94Sfs*24 | Frame Shift Del (DEL) | VAF 20/194 reads (10%) | called by mutect2, pindel
- SLC9A5 | c.607_612del p.F203_I204del | In Frame Del (DEL) | VAF 10/102 reads (10%) | called by mutect2, pindel
- SMCHD1 | c.1808_1811del p.E603Gfs*25 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel, varscan2
- THAP12 | c.1684_1693del p.G562Nfs*4 | Frame Shift Del (DEL) | VAF 9/90 reads (10%) | called by mutect2, pindel
- TMX1 | c.354_364del p.T119Lfs*7 | Frame Shift Del (DEL) | VAF 11/107 reads (10%) | called by mutect2, pindel
- ZNF211 | c.485_486del p.P162Lfs*52 (on ENST00000347302 / NM_198855.4; = p.P175Lfs*52 on NM_006385.5) | Frame Shift Del (DEL) | VAF 23/83 reads (28%) | called by mutect2, pindel, varscan2
- ABCA1 | c.6429A>G p.V2143= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV101037626; called by muse, mutect2, varscan2
- AGAP4 | c.1338G>A p.S446= | Silent (SNP) | VAF 78/196 reads (40%) | catalogued as rs1554896299, COSV101432710; called by muse, mutect2, varscan2
- ANK1 | c.1623C>T p.H541= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as rs750320604, COSV55879085; called by muse, mutect2, varscan2
- C11orf52 | c.276G>T p.V92= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV99585640; called by muse, mutect2, varscan2
- CACNG5 | c.675C>T p.S225= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs780792006, COSV50059404; called by muse, mutect2, varscan2
- COL11A1 | c.3366T>A p.P1122= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV100618013; called by muse, mutect2, varscan2
- COL19A1 | c.1182G>T p.G394= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV100507159, COSV100507488; called by muse, mutect2, varscan2
- DACT1 | c.1284C>A p.A428= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100242114, COSV60023817; called by muse, mutect2
- DENND4A | c.5064A>G p.L1688= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs1366866298, COSV101475430; called by muse, mutect2, varscan2
- DOCK4 | c.5139C>T p.N1713= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as COSV101447969; called by muse, mutect2, varscan2
- ELOA2 | c.2214G>A p.L738= | Silent (SNP) | VAF 24/173 reads (14%) | catalogued as COSV99798018; called by muse, mutect2, varscan2
- FBH1 | c.1122G>T p.T374= (on ENST00000362091 / NM_178150.3; = p.T425= on NM_032807.4) | Silent (SNP) | VAF 19/125 reads (15%) | called by muse, mutect2, varscan2
- GRM3 | c.2424C>T p.S808= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100862884; called by muse, mutect2, varscan2
- HTR1A | c.966G>A p.E322= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100109276; called by muse, mutect2, varscan2
- IGKV1D-17 | c.267T>A p.S89= | Silent (SNP) | VAF 65/183 reads (36%) | called by muse, mutect2, varscan2
- KLHL2 | c.1302T>C p.N434= | Silent (SNP) | VAF 32/215 reads (15%) | catalogued as COSV99900323; called by muse, mutect2, varscan2
- KLHL40 | c.417C>T p.L139= | Silent (SNP) | VAF 57/112 reads (51%) | catalogued as COSV99825763; called by muse, mutect2, varscan2
- LILRB5 | c.9C>T p.L3= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV100300803; called by muse, mutect2, varscan2
- LIN7A | c.33G>T p.T11= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV54029426, COSV99692690; called by muse, mutect2, varscan2
- MAB21L2 | c.772C>A p.R258= | Silent (SNP) | VAF 31/54 reads (57%) | catalogued as COSV100462439; called by muse, mutect2, varscan2
- MBD5 | c.1431A>T p.V477= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV101290269; called by muse, mutect2, varscan2
- NSD1 | c.7143C>A p.P2381= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV100729789; called by muse, mutect2, varscan2
- OR10A7 | c.216T>C p.C72= | Silent (SNP) | VAF 52/232 reads (22%) | catalogued as COSV100406632; called by muse, mutect2, varscan2
- PCCB | c.139C>T p.L47= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99291666; called by muse, mutect2, varscan2
- PCDHA8 | c.2301G>C p.T767= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs1249780500, COSV100970077; called by muse, mutect2, varscan2
- SDK1 | c.4506C>T p.G1502= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV101269836; called by muse, mutect2, varscan2
- SGSM3 | c.339C>T p.A113= | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as rs773553225, COSV99960671; called by muse, mutect2, varscan2
- SLC18A3 | c.1446C>T p.R482= | Silent (SNP) | VAF 42/84 reads (50%) | catalogued as rs1178088349, COSV60335686; called by muse, mutect2, varscan2
- SYNE1 | c.12165C>A p.V4055= (on ENST00000367255 / NM_182961.4; = p.V3984= on NM_033071.3) | Silent (SNP) | VAF 44/86 reads (51%) | catalogued as COSV54948656; called by muse, mutect2, varscan2
- TASOR2 | c.5226G>A p.K1742= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100051010; called by muse, mutect2, varscan2
- TECTA | c.651C>T p.T217= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99881497; called by muse, mutect2, varscan2
- TRPC5 | c.1173A>T p.T391= | Silent (SNP) | VAF 52/84 reads (62%) | catalogued as COSV99462669; called by muse, mutect2, varscan2
- UBE2NL | c.120T>A p.A40= | Silent (SNP) | VAF 57/95 reads (60%) | called by muse, mutect2, varscan2
- WDR72 | c.909C>A p.T303= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV100855068; called by muse, mutect2
- ZNF415 | c.1242C>T p.C414= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as rs771526324, COSV99702029; called by muse, mutect2, varscan2
- BLACAT1 | c.-36-7317_-36-7302del | Intron (DEL) | VAF 20/172 reads (12%) | called by mutect2, pindel
- COPS9 | chr2:240126690 C>A | 3'Flank (SNP) | VAF 43/101 reads (43%) | catalogued as COSV100217144; called by muse, mutect2, varscan2
- NXF5 | n.1129G>A | RNA (SNP) | VAF 15/53 reads (28%) | called by mutect2, varscan2
- PCDHA2 | c.2388+7716C>T | Intron (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100793737; called by muse, mutect2, varscan2
- SLC30A2 | c.271+603C>A | Intron (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100958607, COSV100958622; called by muse, mutect2, varscan2
